Gene-level copy-number profile of tumor specimen TCGA-BC-A69H-01A from TCGA case TCGA-BC-A69H, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 64.0 years (23,380 days).
Specimen TCGA-BC-A69H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.9a911273-31bb-46af-8f1c-90189f3ef5cf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BC-A69H-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/04957486-54d0-4710-8659-8245ad102ce1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3,327; copy number 2: 4,383; copy number 3: 14,454; copy number 4: 22,383; copy number 5: 6,613; copy number 6: 5,931; copy number 7: 357; copy number 8: 348; copy number 9: 217; copy number 10: 1,235; copy number 11: 10; copy number 12: 207; copy number 13: 112; copy number 14: 47; copy number 16: 43; copy number 18: 105; copy number 25: 45.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BC-A69H-01A-11D-A30U-01): tumor purity 0.66, ploidy 4.01, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,021 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:63,011,463–64,833,681, 105 genes, copy number 18 (within-gene range 4–18) (broad region; genes not listed).
- chr7:64,870,172–68,724,048, 100 genes, copy number 13–16 (within-gene range 4–16) (broad region; genes not listed).
- chr7:87,934,143–95,540,233, 118 genes, copy number 12 (within-gene range 3–12) (broad region; genes not listed).
- chr7:116,563,594–123,790,711, 100 genes, copy number 13–25 (broad region; genes not listed).
- chr8:46,028,804–145,066,685, 1,534 genes, copy number 9–12 (broad region; genes not listed).
- chr22:32,507,820–33,058,381, 6 genes, copy number 9 (within-gene range 3–9): SYN3, SYN3-AS1, RNA5SP497, Z73495.1, TIMP3, Z83846.1.
- chr22:33,105,383–33,106,059, 1 gene, copy number 9: Z82198.1.
- chr22:48,403,462–50,327,012, 57 genes, copy number 11–14: Z72006.1, Z82249.1, Z84468.2, TAFA5, Z84468.1, MIR4535, LINC01310, AL078622.1, Z82202.2, RPL35P8, Z82202.1, AC207130.1, C22orf34, AL008636.1, AL031593.1, MIR3667, Z97192.1, Z97192.2, Z97192.3, Z97192.4, AL023802.1, RN7SKP252, RPL5P35, BRD1, Z98885.3, Z98885.1, Z98885.2, AL117328.1, Metazoa_SRP, AL117328.2, ZBED4, ALG12, AL671710.1, CRELD2, BX539320.1, PIM3, MIR6821, IL17REL, TTLL8, MLC1, MOV10L1, AL034546.1, PANX2, TRABD, AL022328.3, AL022328.4, SELENOO, AL022328.1, AL022328.2, TUBGCP6, HDAC10, MAPK12, MAPK11, PLXNB2, DENND6B, CR559946.1, CR559946.2.

Autosomal genes at a single copy (total copy number 1): 947. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
